Somatic mutation profile of tumor specimen C3N-01030-03 (aliquot CPT0091240009) from CPTAC case C3N-01030, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.9 years (20,772 days).
Specimen C3N-01030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80c1b82a-bf2a-4296-89af-81548879bd9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01030-31 (Blood Derived Normal), aliquot CPT0091500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ead7f2-5d41-4c85-a51a-71aac01f7ffe

The open-access MAF lists 952 somatic variants for this specimen: 648 protein-altering or splice-affecting, 195 silent, 109 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 527, Silent 195, Nonsense Mutation 60, Intron 49, Frame Shift Del 29, Splice Site 21, 3'UTR 17, RNA 15, 5'UTR 12, 3'Flank 8, 5'Flank 8, Frame Shift Ins 7.

Variants (750 of 952; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 114/530 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs120074178, CM097143, CM960897; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 120/241 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 89/242 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as COSV65076337; called by muse, mutect2, varscan2
- ADAM7 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs753250327, COSV51541024, COSV51546369; called by muse, mutect2, varscan2
- ADCY2 | c.853del p.R285Gfs*5 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as COSV57886381; called by mutect2, pindel, varscan2
- ADGRL3 | c.1400G>T p.G467V (on ENST00000506720 / NM_001322402.2; = p.G399V on NM_015236.6) | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV72274422; called by muse, mutect2, varscan2
- ADGRV1 | c.16249G>T p.V5417F | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs375876245; called by muse, mutect2, varscan2
- AFAP1L1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs150887335, COSV57044796; called by muse, mutect2
- AGTPBP1 | c.3373G>A p.E1125K (on ENST00000357081 / NM_001330701.2; = p.E1085K on NM_015239.2) | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61276393; called by muse, mutect2, varscan2
- AK7 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as rs755402172, COSV50871793, COSV99967417; called by muse, mutect2, varscan2
- ANKRD30B | c.1927+1G>C p.X643_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99081614; called by muse, mutect2, varscan2
- ANKRD36 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs763419158; called by muse, mutect2, varscan2
- APC | c.2840G>C p.C947S | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.535); catalogued as CD011087, CD104010, CD162633, CM080073, COSV57386197; called by muse, mutect2, varscan2
- ARAP2 | c.1343G>T p.R448M | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.862); catalogued as COSV58283612; called by muse, mutect2, varscan2
- ATF7IP | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 105/202 reads (52%) | catalogued as COSV53776955, COSV99661480; called by muse, mutect2, varscan2
- B3GNTL1 | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100302018; called by muse, varscan2
- BRD1 | c.2860C>T p.R954C (on ENST00000216267 / NM_001349940.1; = p.R1085C on NM_001304808.3) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756317589; called by muse, mutect2, varscan2
- C16orf96 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770766977, COSV71472210; called by muse, mutect2
- CADPS | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV51877820; called by muse, mutect2, varscan2
- CALN1 | c.149G>T p.R50L (on ENST00000329008 / NM_001017440.3; = p.R92L on NM_031468.4) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV61118039, COSV61119958; called by muse, mutect2, varscan2
- CBWD1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 35/176 reads (20%) | catalogued as COSV58703406; called by muse, mutect2, varscan2
- CCDC168 | c.9085A>G p.M3029V | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs750637447; called by muse, mutect2, varscan2
- CCDC7 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV99511378; called by muse, mutect2, varscan2
- CCK | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58184085; called by muse, mutect2, varscan2
- CD209 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV52656359; called by muse, mutect2, varscan2
- CENPE | c.5299G>T p.A1767S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as rs773390883; called by muse, varscan2
- CLEC4F | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV99713450; called by muse, mutect2, varscan2
- CNTNAP5 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs370342488, COSV101444166; called by muse, mutect2, varscan2
- CNTNAP5 | c.2436T>A p.S812R | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs375927406; called by muse, mutect2, varscan2
- COL2A1 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 40/294 reads (14%) | catalogued as COSV61534970; called by muse, mutect2, varscan2
- COL4A2 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs779091629, COSV64625123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC10 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 98/193 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1161127619, COSV60520498; called by muse, mutect2, varscan2
- CORIN | c.2445del p.W815Cfs*25 | Frame Shift Del (DEL) | VAF 39/228 reads (17%) | catalogued as COSV56689403; called by mutect2, pindel, varscan2
- CRACD | c.1985C>G p.A662G | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.061); catalogued as COSV51716434, COSV51717006; called by muse, mutect2, varscan2
- CTSG | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53535762; called by muse, mutect2, varscan2
- CTTN | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 40/184 reads (22%) | catalogued as COSV100097035, COSV57233219; called by muse, mutect2, varscan2
- CUL3 | c.540-2A>T p.X180_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as COSV52369600; called by muse, varscan2
- DCLRE1A | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as rs545969463; called by muse, mutect2, varscan2
- DCN | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV50006041, COSV50008596; called by muse, mutect2, varscan2
- DENND4A | c.2199G>T p.L733F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs763491665; called by muse, mutect2, varscan2
- DSCAM | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101260947; called by muse, mutect2, varscan2
- ECM2 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs763096769, COSV60742206; called by muse, mutect2, varscan2
- ENOX1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54904120; called by muse, mutect2, varscan2
- EPB41L2 | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.706); catalogued as rs776630064; called by muse, mutect2
- EPYC | c.341-1G>C p.X114_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | catalogued as COSV53803068, COSV99664686; called by muse, mutect2
- ERBB4 | c.2080-1G>T p.X694_splice | Splice Site (SNP) | VAF 22/262 reads (8%) | catalogued as COSV99038402, COSV99628344; called by muse, mutect2
- ETFRF1 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs567962579; called by muse, mutect2, varscan2
- EXOSC10 | c.2653A>T p.R885* (on ENST00000376936 / NM_001001998.3; = p.R860* on NM_002685.4) | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | catalogued as rs1317980867; called by muse, mutect2, varscan2
- FAM180A | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | catalogued as COSV100647213; called by muse, mutect2, varscan2
- FBLN2 | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200284680; called by muse, mutect2, varscan2
- FBN2 | c.7856A>G p.D2619G | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99330160; called by muse, mutect2, varscan2
- FBXL7 | c.415C>G p.R139G | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV100309584; called by muse, mutect2
- FGG | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV100272127; called by muse, mutect2, varscan2
- FLG | c.8525G>T p.R2842L | Missense Mutation (SNP) | VAF 246/1496 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100910475, COSV64252567; called by muse, mutect2, varscan2
- FLRT3 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53993132; called by muse, mutect2, varscan2
- FLT4 | c.3412G>T p.E1138* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV56106431; called by muse, mutect2, varscan2
- FOXC2 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100234379; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV63044316; called by muse, mutect2
- FRS3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52484671; called by muse, mutect2
- FSHR | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1336105746, COSV58634968; called by muse, mutect2, varscan2
- GALNT13 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.286); catalogued as COSV67234104; called by muse, mutect2, varscan2
- GLT1D1 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1406294067; called by muse, mutect2, varscan2
- GNRH1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs957377093; called by muse, mutect2, varscan2
- GPR149 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs369856925, COSV67667813, COSV67670238; called by muse, mutect2, varscan2
- GRAMD1B | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100455119; called by muse, mutect2, varscan2
- GRIA4 | c.202del p.V68Wfs*12 | Frame Shift Del (DEL) | VAF 40/196 reads (20%) | catalogued as COSV56908529; called by mutect2, pindel, varscan2
- GRID1 | c.2163C>A p.C721* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as COSV60038776; called by muse, mutect2, varscan2
- GRID2 | c.2153C>A p.S718* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as COSV56192980; called by muse, mutect2, varscan2
- GRIK2 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402876014, COSV59715747, COSV59723303; called by muse, mutect2, varscan2
- GRM7 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.165); catalogued as COSV63143160; called by muse, mutect2, varscan2
- GRM8 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs376815449; called by muse, mutect2, varscan2
- GTF2F1 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99831754; called by muse, mutect2, varscan2
- HGS | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV61266466; called by muse, mutect2, varscan2
- HK3 | c.2410C>G p.R804G | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.378); catalogued as COSV52842174, COSV99457875; called by muse, mutect2, varscan2
- HNRNPCL1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV58611091; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777433485; called by muse, mutect2, varscan2
- IGHV3-33 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs375640211; called by muse, mutect2, varscan2
- IL7R | c.1237A>T p.S413C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs368172701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM122154; called by muse, mutect2, varscan2
- KIF20A | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147723176; called by muse, mutect2, varscan2
- KLK13 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV99335314; called by muse, mutect2, varscan2
- KRT16 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 252/437 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs772428048; called by muse, mutect2, varscan2
- LILRB1 | c.314G>C p.W105S (on ENST00000427581; = p.W69S on NM_006669.6) | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61118024; called by muse, mutect2, varscan2
- LILRB1 | c.1393C>A p.P465T (on ENST00000427581; = p.P429T on NM_006669.6) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs771021905; called by muse, mutect2, varscan2
- LIPI | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV60712160; called by muse, mutect2, varscan2
- LPAR3 | c.130dup p.I44Nfs*5 | Frame Shift Ins (INS) | VAF 25/202 reads (12%) | catalogued as COSV65453292; called by mutect2, pindel, varscan2
- LPCAT1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52036023; called by muse, mutect2, varscan2
- LRP1B | c.8657del p.S2886Mfs*42 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as COSV67222441; called by mutect2, pindel
- LRRC4C | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.99); catalogued as COSV53419909, COSV99538496; called by muse, mutect2, varscan2
- LRRTM3 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as rs1408594600; called by muse, mutect2, varscan2
- LTBP1 | c.2993-1G>T p.X998_splice (on ENST00000404816 / NM_206943.4; = p.X672_splice on NM_000627.4) | Splice Site (SNP) | VAF 27/98 reads (28%) | catalogued as rs370614148; called by mutect2, varscan2
- LTBP2 | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV56213222; called by muse, mutect2, varscan2
- MAGEC3 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 63/123 reads (51%) | catalogued as COSV99036287; called by muse, mutect2, varscan2
- MAGEE1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV100819334; called by muse, mutect2, varscan2
- MAP3K5 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1388373271; called by muse, mutect2, varscan2
- MAP4K3 | c.1973G>T p.R658M | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55719128; called by muse, mutect2, varscan2
- MBTPS1 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.89); catalogued as rs138035660; called by muse, mutect2, varscan2
- MEP1A | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs776059147; called by muse, mutect2, varscan2
- MMRN2 | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64400773; called by muse, mutect2, varscan2
- MRPS15 | c.716G>C p.R239P | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV64152121; called by muse, mutect2, varscan2
- MUC16 | c.18964G>A p.D6322N | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.181); catalogued as rs142913265; called by muse, mutect2, varscan2
- MXRA5 | c.3962C>A p.S1321* | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | catalogued as COSV54234563; called by muse, mutect2, varscan2
- MYO3A | c.4436C>A p.S1479* | Nonsense Mutation (SNP) | VAF 57/253 reads (23%) | catalogued as COSV99777674; called by muse, mutect2, varscan2
- MYO5C | c.751-2A>T p.X251_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55908536; called by muse, mutect2, varscan2
- MYRIP | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs201954262; called by muse, mutect2, varscan2
- MYT1 | c.1510C>A p.H504N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1275548194; called by muse, varscan2
- MYT1L | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762411264; called by muse, mutect2, varscan2
- NALCN | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as rs1335710703, COSV51946337; called by muse, mutect2
- NDUFAF6 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1399892173; called by muse, mutect2, varscan2
- NEXMIF | c.2308A>G p.S770G | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1287283393; called by muse, mutect2, varscan2
- NFS1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1383437475; called by muse, mutect2
- NRXN1 | c.3500G>T p.R1167L | Missense Mutation (SNP) | VAF 92/365 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV58437320, COSV58472735; called by muse, mutect2, varscan2
- NTRK3 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV62295252, COSV62297183; called by muse, mutect2, varscan2
- OBSCN | c.11495A>G p.E3832G | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99477428; called by muse, mutect2, varscan2
- OBSCN | c.16784G>A p.G5595D | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs1394513470; called by muse, mutect2
- OR51D1 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1170102314; called by muse, mutect2, varscan2
- OR52E4 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57625468; called by muse, mutect2, varscan2
- OR5P2 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100271424, COSV61490295; called by muse, mutect2, varscan2
- OR6F1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs768920583, COSV100129402, COSV57469581; called by muse, mutect2
- OR9A4 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs202208130, COSV71885597; called by muse, mutect2, varscan2
- OTOGL | c.6143C>G p.P2048R (on ENST00000547103; = p.P2039R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100087895; called by muse, mutect2, varscan2
- PABPC5 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57042388; called by muse, mutect2, varscan2
- PCARE | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs543584326, COSV59056135, COSV59057126; called by muse, mutect2, varscan2
- PCDHB7 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 110/782 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.822); catalogued as rs782210482; called by muse, mutect2, varscan2
- PCDHGA10 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as rs1244457142; called by muse, mutect2, varscan2
- PCLO | c.15182A>G p.Q5061R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61633508; called by muse, mutect2, varscan2
- PDE11A | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99615334; called by muse, mutect2
- PDE1B | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs761218249, COSV54493926, COSV54496835; called by muse, mutect2, varscan2
- PDE1C | c.1327A>C p.T443P | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100370336; called by muse, mutect2, varscan2
- PDILT | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV56705175, COSV99043630; called by muse, mutect2, varscan2
- PGAP1 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs149238260; called by muse, mutect2, varscan2
- PGLYRP3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as rs771297602, COSV51949579; called by muse, mutect2, varscan2
- PHEX | c.875C>G p.T292S | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.092); catalogued as COSV65075046; called by muse, mutect2, varscan2
- PHF20L1 | c.2301G>T p.K767N | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55199666, COSV99621009; called by muse, mutect2, varscan2
- PHF21B | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1417285328; called by muse, mutect2, varscan2
- PIWIL4 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372125531; called by muse, mutect2, varscan2
- PLB1 | c.3643C>G p.H1215D | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs375247069; called by muse, varscan2
- PLCB2 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV53032086; called by muse, mutect2, varscan2
- PLEKHF1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as rs761833002; called by muse, mutect2, varscan2
- PLXNA4 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV58113377, COSV58165790; called by muse, mutect2, varscan2
- PPDPFL | c.133G>C p.G45R | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV57462036; called by muse, mutect2, varscan2
- PRKCB | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57768797, COSV57799135; called by muse, mutect2
- PROM1 | c.718G>T p.G240* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as COSV101477084; called by muse, mutect2, varscan2
- PSG11 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100106344, COSV60456784; called by muse, mutect2
- PTGFRN | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101277389; called by muse, mutect2
- PTPRS | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs758460182, COSV53610000; called by muse, mutect2, varscan2
- PTPRT | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV61967345; called by muse, mutect2, varscan2
- RAPGEF4 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs974178216; called by muse, mutect2, varscan2
- RBM10 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61308787; called by muse, mutect2, varscan2
- RDX | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1455213377; called by muse, mutect2, varscan2
- REV3L | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs201601521, COSV62616539; called by muse, mutect2, varscan2
- RFTN2 | c.561A>T p.R187S | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1202248520; called by muse, mutect2, varscan2
- RGS9 | c.1674G>T p.E558D | Missense Mutation (SNP) | VAF 161/278 reads (58%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV52227661; called by muse, mutect2, varscan2
- ROBO2 | c.2303A>G p.Q768R | Missense Mutation (SNP) | VAF 77/356 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1377055652; called by muse, mutect2, varscan2
- ROBO2 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV100164631, COSV59936475; called by muse, mutect2, varscan2
- RUSC1 | c.1899C>G p.F633L (on ENST00000368352 / NM_001105203.2; = p.F164L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.086); catalogued as COSV52738727; called by muse, mutect2
- RYR2 | c.7854G>C p.W2618C | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63718213; called by muse, mutect2, varscan2
- RYR3 | c.2259C>G p.I753M | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.645); catalogued as COSV66798231; called by muse, mutect2, varscan2
- RYR3 | c.11835G>T p.K3945N (on ENST00000389232; = p.K3946N on NM_001036.6) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1319476449; called by muse, mutect2, varscan2
- SAE1 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.385); catalogued as COSV54293179; called by muse, mutect2, varscan2
- SEMG1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.728); catalogued as COSV99725638; called by muse, mutect2, varscan2
- SERPING1 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as CM973246, COSV99557878; called by muse, mutect2, varscan2
- SGF29 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs770851630; called by muse, mutect2, varscan2
- SHLD1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV100290778; called by muse, mutect2
- SHROOM2 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV66610284; called by muse, mutect2, varscan2
- SLAMF1 | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52501994; called by muse, mutect2, varscan2
- SLC13A1 | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV52016618; called by muse, mutect2, varscan2
- SLC17A6 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1409446098, COSV54142593; called by muse, mutect2, varscan2
- SLIT3 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100266551; called by muse, mutect2, varscan2
- SPDYE3 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 80/590 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100193897, COSV60107732; called by muse, mutect2, varscan2
- SPON1 | c.1755C>G p.I585M | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1554941704, COSV59958191; called by muse, mutect2, varscan2
- STIL | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867802549, COSV54548753; called by muse, mutect2, varscan2
- SYCN | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1240739078; called by muse, mutect2
- TBC1D30 | c.1912A>G p.N638D (on ENST00000542120; = p.N475D on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1216978360; called by muse, mutect2
- TCTE1 | c.623C>A p.P208Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV65256211; called by muse, mutect2, varscan2
- TENM2 | c.2453G>A p.G818E (on ENST00000518659 / NM_001122679.2; = p.G586E on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319476; called by muse, mutect2, varscan2
- TLCD3B | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV54228417; called by muse, mutect2, varscan2
- TLR1 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138709743, COSV58305968; called by muse, mutect2, varscan2
- TM9SF2 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899676; called by muse, mutect2, varscan2
- TMC7 | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV58583281; called by muse, mutect2, varscan2
- TMEM151A | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59173593; called by muse, mutect2, varscan2
- TMEM26 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV53262761; called by muse, mutect2, varscan2
- TRIM17 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV54383572; called by muse, mutect2, varscan2
- TRIM64B | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs564890926, COSV61693574; called by muse, mutect2, varscan2
- TSPYL5 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59071363; called by muse, mutect2
- TTN | c.84334C>A p.L28112I (on ENST00000591111; = p.L20688I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | PolyPhen probably damaging (0.996); catalogued as COSV59874380; called by muse, mutect2
- UFL1 | c.1986-2A>T p.X662_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as rs868113641; called by muse, varscan2
- UNC5D | c.914del p.C305Ffs*43 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as COSV54791408; called by mutect2, pindel, varscan2
- VCAN | c.9091C>A p.Q3031K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54105753; called by muse, mutect2, varscan2
- VCAN | c.9293G>T p.C3098F | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54104304; called by muse, mutect2, varscan2
- VPREB3 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779221030, COSV50707461; called by muse, mutect2, varscan2
- WASL | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV99771812; called by muse, mutect2
- WNK3 | c.2198C>A p.A733D | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV63615348; called by muse, mutect2, varscan2
- XKR5 | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745353185; called by muse, mutect2
- ZIC1 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs376604833; called by muse, mutect2, varscan2
- ZIC1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs1404263948; called by muse, mutect2, varscan2
- ZNF366 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs759333618; called by muse, mutect2, varscan2
- ZNF716 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV70781145; called by muse, mutect2, varscan2
- ZNF844 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1178919897; called by muse, mutect2
- ZNHIT6 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100995666; called by muse, mutect2, varscan2
- ABCC5 | c.2504A>T p.E835V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- AC004890.2 | n.1599+1G>T | Splice Site (SNP) | VAF 106/277 reads (38%) | called by muse, mutect2, varscan2
- ACAN | c.7068G>T p.E2356D (on ENST00000560601 / NM_001369268.1; = p.E2280D on NM_001135.3) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAP2 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM30 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADAMTS20 | c.3981G>T p.R1327S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTS6 | c.1620+1G>T p.X540_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | called by muse, varscan2
- ADCY10 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 173/436 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADCY5 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRB1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRE1 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 56/197 reads (28%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1073A>T p.N358I (on ENST00000296862 / NM_001368115.2; = p.N290I on NM_153839.7) | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ADGRL1 | c.2761-1G>C p.X921_splice (on ENST00000340736 / NM_001008701.3; = p.X916_splice on NM_014921.5) | Splice Site (SNP) | VAF 31/270 reads (11%) | called by muse, varscan2
- ADORA2A | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- AGPAT1 | c.200+1G>T p.X67_splice | Splice Site (SNP) | VAF 113/220 reads (51%) | called by muse, mutect2, varscan2
- AGRN | c.5336C>G p.A1779G | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHNAK | c.9754G>T p.A3252S | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.8176del p.D2726Mfs*39 | Frame Shift Del (DEL) | VAF 59/257 reads (23%) | called by mutect2, pindel, varscan2
- AHR | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKNA | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ALDH1A1 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX15B | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMBN | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- AMER1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- AMY2B | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ANKFY1 | c.385A>T p.R129* | Nonsense Mutation (SNP) | VAF 62/152 reads (41%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36C | c.4458A>T p.R1486S | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- APLP2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARHGAP17 | c.2156del p.P719Lfs*7 (on ENST00000289968 / NM_001006634.3; = p.P641Lfs*7 on NM_018054.6) | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP18 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARHGAP25 | c.597C>A p.F199L (on ENST00000409202 / NM_001007231.3; = p.F191L on NM_014882.3) | Missense Mutation (SNP) | VAF 78/332 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ARHGEF18 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF37 | c.1643G>T p.W548L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSI | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ARSI | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD2B | c.2035A>T p.I679L | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.275); called by muse, varscan2
- ATAD3C | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP11B | c.3098G>T p.W1033L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATP2B2 | c.2854del p.A953Pfs*41 (on ENST00000352432; = p.A919Pfs*41 on NM_001683.5) | Frame Shift Del (DEL) | VAF 75/358 reads (21%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1738A>T p.K580* | Nonsense Mutation (SNP) | VAF 96/309 reads (31%) | called by muse, mutect2, varscan2
- ATP7B | c.729del p.F243Lfs*19 | Frame Shift Del (DEL) | VAF 78/335 reads (23%) | called by mutect2, pindel, varscan2
- BBS7 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BCAS3 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 100/179 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- BICC1 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BRINP1 | c.132C>G p.D44E | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BRPF3 | c.1738-1G>T p.X580_splice | Splice Site (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- C10orf71 | c.2866G>T p.G956W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C11orf53 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- C16orf82 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- C1QL4 | c.234A>T p.R78S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf198 | c.224T>G p.V75G | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- C1orf94 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- C4orf54 | c.3164G>T p.G1055V | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- C9orf24 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- C9orf40 | c.17del p.A6Gfs*5 | Frame Shift Del (DEL) | VAF 34/143 reads (24%) | called by mutect2, pindel, varscan2
- CA9 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CABIN1 | c.5164G>C p.G1722R | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.3818C>A p.P1273H | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.9477G>T p.L3159F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC175 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC33 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNB1IP1 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CDK13 | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- CENPS-CORT | c.366del p.L124Sfs*2 | Frame Shift Del (DEL) | VAF 31/212 reads (15%) | called by mutect2, pindel, varscan2
- CEP295 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 57/216 reads (26%) | called by muse, mutect2, varscan2
- CHD1L | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD7 | c.6491A>C p.D2164A | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2
- CHST2 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CILK1 | c.1227G>T p.R409S (on ENST00000350082 / NM_001375397.1; = p.R402S on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CNNM2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CNTN6 | c.1445C>A p.T482K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CNTNAP4 | c.1110G>T p.M370I | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.3424A>G p.K1142E | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- COCH | c.1649C>A p.P550H (on ENST00000216361 / NM_001347720.1; = p.P485H on NM_004086.3) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL11A1 | c.614T>A p.V205D | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL23A1 | c.775-1G>T p.X259_splice | Splice Site (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- COLGALT2 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CPA3 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPLANE1 | c.7883C>T p.P2628L | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CREB3L3 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CRTAM | c.987_988del p.L330Rfs*9 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by pindel, varscan2
- CSF1R | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD1 | c.4082C>A p.T1361N (on ENST00000520002; = p.T1360N on NM_033225.6) | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.3373G>T p.E1125* (on ENST00000297405 / NM_001363185.1; = p.E1021* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2
- CST2 | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CST9L | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CUBN | c.9999del p.Q3334Rfs*35 | Frame Shift Del (DEL) | VAF 62/247 reads (25%) | called by mutect2, pindel, varscan2
- CXCL12 | c.127A>T p.N43Y | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CXCL13 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CYP27C1 | c.818A>T p.H273L | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DAPL1 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DBT | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCDC1 | c.2846A>C p.N949T (on ENST00000597505 / NM_001367979.1; = p.N56T on NM_020869.3) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCHS1 | c.9512C>A p.P3171H | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDIAS | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- DDN | c.1002A>T p.Q334H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DDX54 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 44/173 reads (25%) | called by muse, mutect2, varscan2
- DDX60L | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH11 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); called by muse, mutect2
- DNAH3 | c.3414C>A p.D1138E | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH5 | c.12757G>T p.G4253C | Missense Mutation (SNP) | VAF 199/411 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC17 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DOK6 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- DSG1 | c.2825A>T p.E942V | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DST | c.9056C>A p.T3019N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ELAVL2 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EMILIN1 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ENAH | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ENOSF1 | c.1006G>T p.A336S (on ENST00000340116 / NM_001354066.2; = p.A288S on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ENOSF1 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 55/458 reads (12%) | SIFT tolerated, low confidence (0.32); called by muse, varscan2
- EPHA7 | c.576C>A p.C192* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- EPHA8 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERBB4 | c.2928G>T p.R976S | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERICH6 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EYS | c.6487T>A p.F2163I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FA2H | c.729dup p.S244Qfs*69 | Frame Shift Ins (INS) | VAF 84/248 reads (34%) | called by mutect2, pindel, varscan2
- FAM180A | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAM47A | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FAM71A | c.325A>C p.K109Q | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2
- FAN1 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.11842C>T p.Q3948* | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- FBXL7 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 39/445 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2
- FBXO3 | c.1060A>T p.I354F | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FCAR | c.817T>A p.C273S | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FCN3 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FLG2 | c.4276G>C p.E1426Q | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2
- FLG2 | c.4110C>A p.H1370Q | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOLH1 | c.1777C>A p.L593I | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FZD10 | c.1538T>C p.V513A | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); called by muse, mutect2
- GABRA1 | c.1270A>T p.R424* | Nonsense Mutation (SNP) | VAF 53/205 reads (26%) | called by muse, mutect2, varscan2
- GABRA4 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GABRA6 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA6 | c.1255C>A p.Q419K | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRR3 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GALNT13 | c.1361del p.G454Vfs*38 | Frame Shift Del (DEL) | VAF 55/226 reads (24%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.4262A>T p.D1421V (on ENST00000394104; = p.D1430V on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GCLC | c.1611C>G p.I537M (on ENST00000643939; = p.I535M on NM_001498.4) | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GDF10 | c.831del p.A278Qfs*54 | Frame Shift Del (DEL) | VAF 37/167 reads (22%) | called by mutect2, pindel, varscan2
- GDF6 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 120/629 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLIPR1L2 | c.671-1G>T p.X224_splice | Splice Site (SNP) | VAF 32/119 reads (27%) | called by mutect2, varscan2
- GLOD4 | c.413A>T p.Y138F (on ENST00000301328 / NM_001366247.1; = p.Y123F on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLUD2 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GOLGA8N | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 117/912 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH2 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- GPR89B | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRIN3 | c.2100G>T p.L700F | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRAMD1B | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GREB1 | c.4248C>A p.D1416E | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HCFC1R1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- HEATR5B | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- HEPACAM | c.758T>A p.L253H | Missense Mutation (SNP) | VAF 84/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPHL1 | c.1696C>A p.L566I | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HIVEP3 | c.6178G>T p.D2060Y | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- HMCN2 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- HMGXB3 | c.835A>T p.K279* (on ENST00000613459; = p.K33* on NM_014983.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- HNF1A | c.1685C>G p.A562G | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- HOOK3 | c.1234-1G>T p.X412_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- HOXA10 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- HOXC12 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST6 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSD3B2 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSPA12B | c.1493C>A p.A498E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ICE1 | c.5551G>T p.D1851Y | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IFI6 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFIT2 | c.1343A>T p.Q448L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- IL2RG | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS4 | c.2456C>A p.P819H | Missense Mutation (SNP) | VAF 114/200 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- IRS4 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 91/163 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ITGA8 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.681C>A p.Y227* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- ITGAX | c.3328G>T p.V1110L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ITGB1BP2 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- KALRN | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KASH5 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNMA1 | c.1196dup p.S400Lfs*3 | Frame Shift Ins (INS) | VAF 75/357 reads (21%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.4082G>T p.C1361F (on ENST00000619416 / NM_001244190.2; = p.C1300F on NM_014749.5) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KIAA0825 | c.1205A>T p.E402V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- KIAA2026 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KIF21B | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIF2A | c.2111G>T p.R704L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- KMO | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KRT2 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KRT77 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KRTAP13-2 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP2-4 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAMA1 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB1 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- LCOR | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LCP1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- LGR5 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LIFR | c.1465A>T p.N489Y | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- LILRA6 | c.1184G>T p.R395M | Missense Mutation (SNP) | VAF 74/553 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LILRB1 | c.2092C>G p.L698V (on ENST00000427581; = p.L647V on NM_006669.6) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- LILRB5 | c.1337C>G p.T446R (on ENST00000449561 / NM_001081442.3; = p.T445R on NM_006840.5) | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LIN7A | c.91A>T p.R31* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- LIPE | c.1928C>A p.S643* | Nonsense Mutation (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- LMLN | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LMO2 | c.392T>A p.V131E (on ENST00000395833 / NM_001142315.2; = p.V200E on NM_005574.4) | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC7 | c.1318C>A p.Q440K (on ENST00000651989 / NM_001370785.2; = p.Q407K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- LRRN2 | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM4 | c.1128A>T p.Q376H | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MAGEA12 | c.681_682del p.L228Gfs*4 | Frame Shift Del (DEL) | VAF 110/261 reads (42%) | called by pindel, varscan2
- MAGEB4 | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAK | c.629_630del p.F210* | Frame Shift Del (DEL) | VAF 26/247 reads (11%) | called by mutect2, pindel, varscan2
- MAN1A1 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K6 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAP4K4 | c.2923G>T p.G975C (on ENST00000347699 / NM_001242559.2; = p.G893C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.481A>T p.R161* | Nonsense Mutation (SNP) | VAF 125/217 reads (58%) | called by muse, mutect2, varscan2
- MARCHF5 | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MASTL | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- MGAT4C | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MLF1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLIP | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLXIP | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMP8 | c.102+1G>T p.X34_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | called by muse, varscan2
- MMP8 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MON1B | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- MRAP2 | c.74A>T p.Y25F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRC1 | c.1576del p.A526Qfs*14 | Frame Shift Del (DEL) | VAF 47/257 reads (18%) | called by mutect2, pindel, varscan2
- MTHFR | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MTUS2 | c.629dup p.G211Wfs*23 | Frame Shift Ins (INS) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- MUC12 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MUC12 | c.16223G>T p.R5408L (on ENST00000379442; = p.R5265L on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.5); called by muse, mutect2, varscan2
- MUC12 | c.16299C>G p.I5433M (on ENST00000379442; = p.I5290M on NM_001164462.1) | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC17 | c.7664C>A p.S2555Y | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MUC2 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC4 | c.13228A>G p.T4410A (on ENST00000463781 / NM_018406.7; = p.T174A on NM_004532.6) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC5B | c.15760G>T p.D5254Y | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYO19 | c.1696del p.L566Cfs*27 | Frame Shift Del (DEL) | VAF 33/72 reads (46%) | called by mutect2, pindel, varscan2
- MYOM2 | c.1805C>A p.P602H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MZT2A | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- NAV3 | c.4500C>G p.N1500K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NELL2 | c.2263T>A p.C755S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEU4 | c.394G>T p.A132S (on ENST00000391969 / NM_001167602.3; = p.A144S on NM_080741.4) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NFIC | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFKBIZ | c.953_957del p.Q318Pfs*4 | Frame Shift Del (DEL) | VAF 48/198 reads (24%) | called by mutect2, pindel, varscan2
- NLRP10 | c.1961A>G p.Y654C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP14 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | called by mutect2, varscan2
- NLRP9 | c.1775C>A p.T592K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOS1 | c.1594A>T p.N532Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NOVA1 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NPAP1 | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NRF1 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 147/394 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUTM2B | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- NYNRIN | c.5434G>T p.A1812S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OCA2 | c.1693A>T p.S565C | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OMA1 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OPRK1 | c.209T>C p.F70S | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2
- OR10A2 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OR11H6 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR13C4 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- OR14K1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 35/469 reads (7%) | called by muse, mutect2
- OR1N2 | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- OR2F1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- OR2L5 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 39/406 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2
- OR56A5 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5H2 | c.252del p.M86Cfs*11 | Frame Shift Del (DEL) | VAF 53/241 reads (22%) | called by mutect2, pindel, varscan2
- OR6X1 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR7C2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR9Q2 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OSBP2 | c.657A>T p.E219D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBP2 | c.1286A>G p.K429R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.084); called by mutect2, varscan2
- OSCAR | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OTOG | c.2564C>A p.P855H | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOG | c.7825_7828del p.Q2609Vfs*74 | Frame Shift Del (DEL) | VAF 43/173 reads (25%) | called by mutect2, pindel, varscan2
- PAH | c.1176T>A p.F392L | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PAK5 | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PALLD | c.718dup p.R240Kfs*54 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- PAX4 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PAX6 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH10 | c.1210del p.R404Afs*28 | Frame Shift Del (DEL) | VAF 63/257 reads (25%) | called by mutect2, pindel, varscan2
- PCDH11X | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDH15 | c.5218G>T p.E1740* | Nonsense Mutation (SNP) | VAF 67/346 reads (19%) | called by muse, mutect2, varscan2
- PCDH8 | c.1684T>A p.Y562N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDHA2 | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE1C | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDIA4 | c.1693G>T p.V565L (on ENST00000286091 / NM_001371244.1; = p.V564L on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PDILT | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKP | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM5 | c.1032G>T p.M344I | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 34/178 reads (19%) | called by muse, varscan2
- PIWIL1 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PKHD1 | c.5980G>T p.G1994* | Nonsense Mutation (SNP) | VAF 92/335 reads (27%) | called by muse, mutect2, varscan2
- PLCL1 | c.2982G>T p.Q994H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEKHA7 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PLEKHG3 | c.1712G>A p.S571N (on ENST00000394691; = p.S627N on NM_001308147.2) | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- PLXNA2 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 117/254 reads (46%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLQ | c.3697G>T p.V1233F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- POU5F2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PPM1A | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PPP1R26 | c.3441del p.K1148Rfs*6 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- PRAM1 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PRDM10 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM9 | c.960C>A p.N320K | Missense Mutation (SNP) | VAF 101/448 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PRMT5 | c.155G>T p.R52M | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRRC2C | c.5828A>T p.Q1943L (on ENST00000367742; = p.Q1941L on NM_015172.4) | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PRSS37 | c.490del p.Q164Kfs*15 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.4796T>A p.V1599E | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG1 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG9 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTPDC1 | c.1915C>G p.L639V (on ENST00000375360 / NM_177995.3; = p.L691V on NM_152422.4) | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PTPN5 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRN2 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 187/513 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PUM3 | c.956+1G>T p.X319_splice | Splice Site (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- RAD50 | c.3695A>T p.E1232V | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- RALGAPA2 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RAP1GDS1 | c.74G>T p.G25V (on ENST00000408927 / NM_001100427.2; = p.G26V on NM_021159.5) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RAPSN | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- RASGRP1 | c.36-6C>T | Splice Region (SNP) | VAF 69/228 reads (30%) | called by muse, mutect2, varscan2
- RASSF10 | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASSF10 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM33 | c.2687C>T p.S896F | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.805); called by muse, mutect2
- RC3H1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RDH8 | c.419G>T p.R140L (on ENST00000651512; = p.R120L on NM_015725.4) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RELN | c.5981C>A p.S1994* | Nonsense Mutation (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- RET | c.2388G>T p.Q796H | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFPL4A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RFPL4A | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RIT2 | c.366C>G p.H122Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- RP1L1 | c.3017C>A p.P1006Q | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RPE65 | c.1237C>G p.R413G | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- RPTOR | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 113/197 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RUBCNL | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RUNX1T1 | c.1033C>G p.L345V (on ENST00000265814 / NM_001198628.1; = p.L318V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RUVBL2 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.119); called by muse, mutect2
- RXFP2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.3139G>T p.G1047C | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SAFB | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, varscan2
- SAG | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK1 | c.4129G>T p.A1377S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SEL1L2 | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- SERPINA11 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SF3A2 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFMBT2 | c.1535T>A p.L512* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- SGK2 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3PXD2B | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3TC2 | c.3553G>C p.A1185P | Missense Mutation (SNP) | VAF 110/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3TC2 | c.3204+2T>C p.X1068_splice | Splice Site (SNP) | VAF 58/257 reads (23%) | called by muse, mutect2, varscan2
- SHANK1 | c.4945G>T p.G1649C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SIGLEC1 | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SIGLEC8 | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC13A1 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC13A3 | c.45del p.R16Gfs*46 | Frame Shift Del (DEL) | VAF 37/145 reads (26%) | called by mutect2, pindel, varscan2
- SLC16A1 | c.1399A>T p.S467C | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SLC16A5 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 165/269 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A6 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by mutect2, varscan2
- SLC30A7 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- SLC45A2 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 28/315 reads (9%) | called by muse, mutect2
- SLC45A3 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- SLC45A3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2
- SLC4A8 | c.3229A>G p.K1077E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- SLC5A12 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A4 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC9A3 | c.2499C>A p.H833Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); called by muse, varscan2
- SLIT3 | c.4358T>A p.V1453E | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLITRK1 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SLITRK2 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SMCHD1 | c.4282-1G>T p.X1428_splice | Splice Site (SNP) | VAF 34/176 reads (19%) | called by mutect2, varscan2
- SMOC1 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORBS1 | c.2724G>T p.R908S (on ENST00000361941 / NM_001034954.2; = p.R558S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPATA17 | c.317G>T p.R106M | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SPATA31A1 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 131/534 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SPTA1 | c.6530+5G>T | Splice Region (SNP) | VAF 181/470 reads (39%) | called by muse, mutect2, varscan2
- SRRM5 | c.1771A>G p.R591G | Missense Mutation (SNP) | VAF 151/457 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SSH3 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 48/364 reads (13%) | called by muse, mutect2, varscan2
- STAB2 | c.2420G>T p.G807V | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STEAP2 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- STON2 | c.415del p.D139Tfs*8 | Frame Shift Del (DEL) | VAF 68/228 reads (30%) | called by mutect2, pindel, varscan2
- SUCLG1 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 109/430 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SULT1E1 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SV2C | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- SYN3 | c.744del p.K248Nfs*59 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel*, varscan2
- TACC2 | c.1921G>C p.A641P | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACR3 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TAS2R43 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); called by muse, varscan2
- TBC1D8 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TBL2 | c.457G>T p.V153F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TBX19 | c.1117G>C p.V373L | Missense Mutation (SNP) | VAF 207/506 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBX4 | c.1146C>A p.Y382* | Nonsense Mutation (SNP) | VAF 191/326 reads (59%) | called by muse, mutect2, varscan2
- TCF7L2 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD7 | c.1448dup p.K485Qfs*13 | Frame Shift Ins (INS) | VAF 62/281 reads (22%) | called by mutect2, pindel, varscan2
- TENM2 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.4232C>A p.S1411Y | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TEX15 | c.2092C>A p.H698N (on ENST00000256246; = p.H1081N on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TEX15 | c.2091C>A p.S697R (on ENST00000256246; = p.S1080R on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TGFBR2 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGFBR3 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THSD7A | c.2561G>T p.S854I | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM201 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- TMEM38A | c.800G>T p.S267I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM41B | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TNNT1 | c.128+8C>A | Splice Region (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- TPBGL | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TRA2A | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- TRAJ14 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- TRPC7 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TSHR | c.1504G>C p.V502L | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TTC16 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TTF1 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.36305T>A p.L12102Q (on ENST00000591111; = p.L4678Q on NM_003319.4) | Missense Mutation (SNP) | VAF 33/193 reads (17%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2F | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- UBR3 | c.4220G>T p.G1407V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UNC13B | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UNC5A | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5A | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- URB1 | c.5426G>C p.G1809A | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- USH2A | c.12041C>A p.P4014H | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.65); called by muse, mutect2
- USP5 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- VAV2 | c.1188+2T>G p.X396_splice (on ENST00000371850 / NM_001134398.2; = p.X391_splice on NM_003371.4) | Splice Site (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- VCAN | c.1645G>T p.G549* | Nonsense Mutation (SNP) | VAF 45/362 reads (12%) | called by muse, mutect2, varscan2
- VCAN | c.4516T>A p.F1506I | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13B | c.8447C>T p.S2816L | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2
- VPS8 | c.730G>T p.G244* (on ENST00000625842 / NM_001349294.1; = p.G242* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- VWF | c.6718G>T p.D2240Y | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WFDC2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WHAMM | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- WNT9A | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWP1 | c.2127G>A p.W709* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- YTHDC1 | c.1602-1G>T p.X534_splice (on ENST00000344157 / NM_001031732.4; = p.X516_splice on NM_133370.4) | Splice Site (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- ZAN | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- ZAR1L | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, varscan2
- ZAR1L | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 29/208 reads (14%) | called by muse, varscan2
- ZBED9 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ZC3H11A | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, varscan2
- ZDHHC17 | c.1121G>T p.W374L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZFHX4 | c.7997G>T p.R2666L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZIC1 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF100 | c.495A>T p.L165F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF114 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF226 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ZNF287 | c.1611_1612dup p.C538Yfs*228 | Frame Shift Ins (INS) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- ZNF469 | c.8862T>A p.D2954E (on ENST00000437464; = p.D2982E on NM_001367624.2) | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF492 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, varscan2
- ZNF492 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ZNF534 | c.431G>T p.G144V (on ENST00000332323 / NM_001143939.3; = p.G131V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF569 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- ZNF624 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF697 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ZNF865 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated, low confidence (0.28); called by muse, varscan2
- ZNF99 | c.964T>A p.F322I | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF99 | c.368del p.G123Vfs*29 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ABCF2 | c.645G>C p.L215= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- AC010522.1 | c.18G>T p.P6= | Silent (SNP) | VAF 89/304 reads (29%) | catalogued as COSV57149865; called by muse, mutect2, varscan2
- ACO1 | c.2391C>A p.A797= | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as rs776083510, COSV59378903; called by muse, mutect2, varscan2
- ADAM18 | c.781C>A p.R261= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs141094631; called by muse, mutect2, varscan2
- ADAM18 | c.969T>A p.L323= | Silent (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2514C>A p.S838= (on ENST00000506720 / NM_001322402.2; = p.S770= on NM_015236.6) | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as COSV104438812; called by muse, mutect2, varscan2
- AGT | c.426C>G p.T142= | Silent (SNP) | VAF 97/851 reads (11%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1257C>T p.F419= | Silent (SNP) | VAF 110/266 reads (41%) | catalogued as rs768625560; called by muse, mutect2, varscan2
- ANK2 | c.9762C>A p.V3254= | Silent (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- ANO1 | c.621C>T p.P207= | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- AP002512.3 | c.1020G>T p.A340= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- APOB | c.11160C>A p.S3720= | Silent (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
- APOB | c.7665T>A p.T2555= | Silent (SNP) | VAF 71/294 reads (24%) | called by muse, mutect2, varscan2
- AQP12B | c.345C>A p.T115= (on ENST00000621682; = p.T127= on NM_001102467.2) | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV101315831; called by muse, mutect2, varscan2
- ASTN1 | c.1686A>T p.S562= | Silent (SNP) | VAF 21/281 reads (7%) | called by muse, mutect2
- ATP8B4 | c.1551C>A p.T517= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- BAZ1B | c.2226A>T p.S742= | Silent (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- BHLHA15 | c.489G>T p.A163= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as COSV51997157; called by muse, varscan2
- BICRA | c.1014G>T p.P338= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- C17orf49 | c.120G>A p.A40= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs975313736; called by muse, mutect2, varscan2
- C8orf74 | c.426G>T p.L142= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- CASP14 | c.702C>A p.T234= | Silent (SNP) | VAF 60/222 reads (27%) | called by muse, varscan2
- CATSPER1 | c.1654C>A p.R552= | Silent (SNP) | VAF 59/238 reads (25%) | catalogued as COSV100375836; called by muse, mutect2, varscan2
- CD44 | c.549C>T p.S183= | Silent (SNP) | VAF 112/418 reads (27%) | called by muse, mutect2, varscan2
- CEP164 | c.3474G>A p.L1158= | Silent (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- CEP192 | c.7350G>T p.P2450= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs530959036; called by muse, mutect2, varscan2
- CFAP100 | c.801G>A p.S267= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as rs757315451, COSV61502891; called by muse, mutect2, varscan2
- CLCN7 | c.1410G>T p.P470= | Silent (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- CLDN8 | c.675G>A p.V225= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs756882658; called by muse, mutect2, varscan2
- CNIH3 | c.279G>C p.L93= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV55273692; called by muse, mutect2, varscan2
- CNMD | c.888C>A p.I296= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs1566214842; called by muse, mutect2, varscan2
- COL11A1 | c.3204T>A p.A1068= | Silent (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- COL6A2 | c.2883G>A p.A961= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs369756029; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- COL6A3 | c.9066C>A p.L3022= | Silent (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
- CPNE7 | c.1332C>A p.P444= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- CRACD | c.2775C>T p.S925= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV51719792; called by muse, varscan2
- CRACD | c.2793G>T p.V931= | Silent (SNP) | VAF 36/148 reads (24%) | called by muse, varscan2
- CRYBG2 | c.747T>C p.P249= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.7815C>A p.A2605= (on ENST00000520002; = p.A2604= on NM_033225.6) | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- CSMD1 | c.3324T>C p.S1108= (on ENST00000520002; = p.S1107= on NM_033225.6) | Silent (SNP) | VAF 15/143 reads (10%) | called by muse, varscan2
- CSMD1 | c.2655C>G p.R885= (on ENST00000520002; = p.R884= on NM_033225.6) | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV59334646; called by muse, mutect2, varscan2
- CUL5 | c.1929C>T p.L643= | Silent (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- CYP27C1 | c.768G>T p.L256= | Silent (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- CYP2C18 | c.372G>T p.R124= | Silent (SNP) | VAF 45/187 reads (24%) | called by muse, mutect2, varscan2
- DCDC1 | c.2529G>T p.G843= | Silent (SNP) | VAF 44/184 reads (24%) | called by muse, varscan2
- DCDC1 | c.2437C>T p.L813= | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, varscan2
- DLX1 | c.291C>A p.A97= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- DMXL2 | c.4035A>T p.P1345= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- DNMBP | c.186C>G p.P62= | Silent (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- DNMT1 | c.822G>A p.E274= | Silent (SNP) | VAF 113/594 reads (19%) | called by muse, mutect2, varscan2
- DUSP21 | c.348G>T p.L116= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV59134027; called by muse, mutect2, varscan2
- EFHD1 | c.351G>A p.L117= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- ELOA2 | c.954C>A p.P318= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2709G>A p.E903= | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as COSV59447832; called by muse, mutect2
- EPPK1 | c.5355C>A p.R1785= | Silent (SNP) | VAF 19/269 reads (7%) | called by muse, mutect2
- EPRS1 | c.2478G>T p.L826= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- EVX2 | c.885G>A p.A295= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs750831697; called by muse, mutect2, varscan2
- EXOSC8 | c.132C>T p.T44= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs751422606; called by muse, mutect2, varscan2
- EYS | c.3129C>A p.A1043= | Silent (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- EZH2 | c.1524G>A p.L508= (on ENST00000460911 / NM_001203247.2; = p.L513= on NM_004456.5) | Silent (SNP) | VAF 32/208 reads (15%) | called by mutect2, varscan2
- FAM131B | c.873G>C p.R291= | Silent (SNP) | VAF 69/408 reads (17%) | called by muse, mutect2, varscan2
- FAM135B | c.949C>T p.L317= | Silent (SNP) | VAF 50/301 reads (17%) | catalogued as rs1312055298; called by muse, mutect2, varscan2
- FIBCD1 | c.1101C>A p.T367= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- FRMPD2 | c.960C>T p.A320= | Silent (SNP) | VAF 47/213 reads (22%) | called by muse, mutect2, varscan2
- FSD2 | c.2172C>A p.P724= | Silent (SNP) | VAF 51/159 reads (32%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.543G>A p.K181= | Silent (SNP) | VAF 90/284 reads (32%) | called by muse, mutect2, varscan2
- GLUD2 | c.27G>T p.L9= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- GOLGA3 | c.3564G>A p.V1188= | Silent (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- GOLGA8H | c.537G>A p.E179= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs1178578346; called by muse, mutect2, varscan2
- GOLPH3 | c.762T>A p.A254= | Silent (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- GPATCH2 | c.789C>T p.L263= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1329C>A p.A443= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- HAND2 | c.309C>T p.T103= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as COSV64018304; called by muse, mutect2
- HAS1 | c.825C>A p.S275= | Silent (SNP) | VAF 98/426 reads (23%) | called by muse, mutect2, varscan2
- HCAR2 | c.213G>A p.V71= | Silent (SNP) | VAF 81/328 reads (25%) | catalogued as rs200828023, COSV61024936; called by muse, mutect2, varscan2
- HJURP | c.1329G>C p.R443= | Silent (SNP) | VAF 65/281 reads (23%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.126T>A p.T42= | Silent (SNP) | VAF 115/462 reads (25%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1917T>A p.P639= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56269742; called by muse, mutect2, varscan2
- ILDR2 | c.1387C>A p.R463= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV54831325; called by muse, mutect2, varscan2
- INHBA | c.1074A>T p.I358= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV54221891; called by muse, mutect2, varscan2
- ITGAX | c.3000A>T p.S1000= | Silent (SNP) | VAF 17/220 reads (8%) | called by muse, mutect2
- ITIH6 | c.3441C>T p.V1147= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as COSV99513232; called by muse, mutect2, varscan2
- JUND | c.1038G>C p.A346= | Silent (SNP) | VAF 148/438 reads (34%) | called by muse, mutect2, varscan2
- KCNJ14 | c.369G>T p.P123= | Silent (SNP) | VAF 93/351 reads (26%) | catalogued as rs746168069; called by muse, mutect2, varscan2
- KCNV1 | c.891G>T p.G297= | Silent (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- KDM2A | c.588G>T p.V196= | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- KIF1A | c.4567C>A p.R1523= (on ENST00000320389 / NM_001379639.1; = p.R1515= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- KIF26A | c.708C>T p.V236= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1216692594; called by muse, mutect2, varscan2
- KIR3DL3 | c.1017C>A p.L339= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- KRT16 | c.1206C>A p.I402= | Silent (SNP) | VAF 254/451 reads (56%) | called by muse, mutect2, varscan2
- KRT85 | c.1011G>A p.E337= | Silent (SNP) | VAF 538/1000 reads (54%) | called by muse, mutect2, varscan2
- LAMB3 | c.1632G>T p.P544= | Silent (SNP) | VAF 77/137 reads (56%) | catalogued as rs753960912, COSV100620549, COSV61919620; called by muse, mutect2, varscan2
- LRCH3 | c.2016G>A p.V672= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- LRRTM1 | c.207C>A p.G69= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2757G>A p.L919= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV58566893; called by muse, mutect2, varscan2
- MAN2C1 | c.2646C>G p.L882= | Silent (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- MAST3 | c.3909C>T p.L1303= | Silent (SNP) | VAF 36/384 reads (9%) | catalogued as rs752550205; called by muse, mutect2
- MCM3AP | c.2205G>T p.T735= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs769036222; called by muse, mutect2
- MEN1 | c.678G>T p.L226= | Silent (SNP) | VAF 66/306 reads (22%) | catalogued as COSV53649839; called by muse, varscan2
- MPP4 | c.189G>A p.Q63= | Silent (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- MTHFS | c.507C>T p.Y169= | Silent (SNP) | VAF 81/318 reads (25%) | catalogued as rs1227082440; called by muse, mutect2, varscan2
- MTUS2 | c.498C>A p.T166= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as rs755722671; called by muse, mutect2, varscan2
202 further variants in this file (0 protein-altering or splice-affecting, 93 silent, 109 other) are not listed here.
